Somatic mutation profile of tumor specimen ALCH-AEJ6-TTP1-A (aliquot ALCH-AEJ6-TTP1-A-1-0-D-A596-36) from ALCHEMIST case ALCH-AEJ6, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 54.6 years (19,944 days).
Specimen ALCH-AEJ6-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22efe9fe-2115-4510-8ad4-9c1c05c66672.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEJ6-NB1-A (Blood Derived Normal), aliquot ALCH-AEJ6-NB1-A-1-0-D-A596-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10bf4dac-bcf6-41cc-bd5d-dcb689bef4df

The open-access MAF lists 573 somatic variants for this specimen: 400 protein-altering or splice-affecting, 110 silent, 63 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 340, Silent 110, Intron 30, Frame Shift Del 19, Nonsense Mutation 16, Splice Site 16, RNA 15, 3'UTR 7, Splice Region 6, 5'UTR 5, 5'Flank 5, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 6/44 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913482, CM950469, COSV53390662; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- RB1 | c.1735C>T p.R579* | Nonsense Mutation (SNP) | VAF 29/335 reads (9%) | hotspot (GDC flag); catalogued as rs121913305, CM941206, COSV57294317, COSV99923811; ClinVar: pathogenic; called by muse, mutect2
- SCN2A | c.4886G>A p.R1629H | Missense Mutation (SNP) | VAF 70/555 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as rs796053157, CM139616; ClinVar: pathogenic / likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TGFBR2 | c.1609C>T p.R537C | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104893809, CM042122, CM064325, COSV55442890; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.536A>T p.H179L | Missense Mutation (SNP) | VAF 151/402 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.12); PolyPhen benign (0.396); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADGRF5 | c.1943C>T p.A648V | Missense Mutation (SNP) | VAF 24/210 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1351047640; called by muse, mutect2, varscan2
- ADGRL4 | c.1519T>C p.W507R | Missense Mutation (SNP) | VAF 40/467 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1402931847; called by muse, mutect2
- AHDC1 | c.2389G>A p.E797K | Missense Mutation (SNP) | VAF 24/207 reads (12%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.982); catalogued as rs777057831; called by muse, mutect2, varscan2
- AHI1 | c.1975G>C p.D659H | Missense Mutation (SNP) | VAF 30/290 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1323210459; called by muse, mutect2, varscan2
- AKIRIN2 | c.574C>T p.R192* | Nonsense Mutation (SNP) | VAF 24/228 reads (11%) | catalogued as COSV57636973; called by muse, mutect2, varscan2
- ANK2 | c.5190A>T p.K1730N | Missense Mutation (SNP) | VAF 31/243 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV52157776; called by muse, mutect2, varscan2
- APOL5 | c.67G>A p.G23S | Missense Mutation (SNP) | VAF 51/198 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as rs1181962264, COSV50767208; called by muse, mutect2, varscan2
- ARFGEF1 | c.2794G>T p.V932F | Missense Mutation (SNP) | VAF 50/409 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.21); catalogued as rs1446120711; called by muse, mutect2, varscan2
- ARHGAP27 | c.2173G>A p.G725R (on ENST00000428638 / NM_001282290.1; = p.G384R on NM_199282.3) | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1296423975; called by mutect2, varscan2
- BRAF | c.2199G>T p.M733I (on ENST00000288602 / NM_001374244.1; = p.M693I on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/345 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as COSV56137363; called by muse, mutect2, varscan2
- CAPN8 | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 38/342 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.769); catalogued as rs778786142; called by muse, mutect2, varscan2
- CCDC93 | c.1297-1G>A p.X433_splice | Splice Site (SNP) | VAF 28/233 reads (12%) | catalogued as rs1460867790; called by muse, mutect2, varscan2
- CCP110 | c.1154C>T p.A385V | Missense Mutation (SNP) | VAF 69/387 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.07); catalogued as rs142177955; called by muse, mutect2, varscan2
- CDH10 | c.1502C>T p.A501V | Missense Mutation (SNP) | VAF 34/287 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.476); catalogued as rs544303560, COSV52580956; called by muse, mutect2, varscan2
- CILP2 | c.3007C>G p.R1003G | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV52279043, COSV99364822; called by muse, mutect2, varscan2
- CNR1 | c.306C>A p.F102L | Missense Mutation (SNP) | VAF 50/343 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV62991550; called by muse, mutect2, varscan2
- CNTN4 | c.2299G>T p.V767L | Missense Mutation (SNP) | VAF 107/402 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs200039799, COSV61867169; called by muse, mutect2, varscan2
- COL2A1 | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 28/431 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.022); catalogued as rs1234615322; called by muse, mutect2
- COL4A4 | c.2101G>T p.G701C | Missense Mutation (SNP) | VAF 66/372 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.019); catalogued as COSV61630659; called by muse, mutect2, varscan2
- COP1 | c.1027-1G>A p.X343_splice | Splice Site (SNP) | VAF 26/117 reads (22%) | catalogued as rs1337206615; called by muse, mutect2, varscan2
- CSGALNACT2 | c.1051G>T p.V351L | Missense Mutation (SNP) | VAF 39/234 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs775076615; called by muse, mutect2, varscan2
- CSMD3 | c.9818G>C p.C3273S (on ENST00000297405 / NM_001363185.1; = p.C3104S on NM_052900.3) | Missense Mutation (SNP) | VAF 82/490 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1447711245; called by muse, mutect2, varscan2
- CWH43 | c.283G>T p.V95F | Missense Mutation (SNP) | VAF 58/435 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.153); catalogued as COSV99894374; called by muse, mutect2, varscan2
- DMD | c.6913-1G>T p.X2305_splice | Splice Site (SNP) | VAF 64/194 reads (33%) | catalogued as CS132450, COSV100629174; called by muse, mutect2, varscan2
- EDNRB | c.1058C>G p.T353R (on ENST00000377211 / NM_001201397.1; = p.T263R on NM_000115.5) | Missense Mutation (SNP) | VAF 50/346 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.288); catalogued as COSV57524969, COSV57529053; called by muse, mutect2, varscan2
- F13A1 | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 175/599 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV53564226; called by muse, mutect2, varscan2
- F8 | c.2072C>T p.P691L | Missense Mutation (SNP) | VAF 86/263 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM0910949; called by muse, mutect2, varscan2
- FAH | c.607-2A>G p.X203_splice | Splice Site (SNP) | VAF 56/442 reads (13%) | catalogued as rs545534156; called by mutect2, varscan2
- FPR2 | c.244A>G p.I82V | Missense Mutation (SNP) | VAF 37/229 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as rs553531100, COSV60672473; called by muse, mutect2, varscan2
- FSCB | c.535G>T p.E179* | Nonsense Mutation (SNP) | VAF 50/230 reads (22%) | catalogued as COSV61218110; called by muse, mutect2, varscan2
- FZD10 | c.568G>A p.G190S | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV57475620; called by muse, mutect2
- GABRB3 | c.178G>T p.D60Y | Missense Mutation (SNP) | VAF 34/190 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.267); catalogued as rs1304603905; called by muse, mutect2, varscan2
- GABRB3 | c.177T>A p.N59K | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.069); catalogued as rs747996609; called by muse, mutect2, varscan2
- GALNT17 | c.1247C>T p.A416V | Missense Mutation (SNP) | VAF 37/292 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs972749747, COSV61158751; called by muse, mutect2, varscan2
- GBF1 | c.4565G>T p.R1522L (on ENST00000369983 / NM_001377137.1; = p.R1521L on NM_004193.3) | Missense Mutation (SNP) | VAF 43/184 reads (23%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.523); catalogued as rs1380564955, COSV64144700; called by muse, mutect2, varscan2
- GJD2 | c.322C>A p.R108S | Missense Mutation (SNP) | VAF 57/449 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV51747190; called by muse, mutect2, varscan2
- GOLGA4 | c.5430G>T p.L1810F | Missense Mutation (SNP) | VAF 72/217 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs769203935; called by muse, mutect2, varscan2
- GRIN3A | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 32/384 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs924402957, COSV62452694; called by muse, mutect2
- H3C10 | c.407C>A p.A136D | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.582); catalogued as rs779961504; called by muse, mutect2, varscan2
- HIVEP2 | c.1606G>T p.D536Y | Missense Mutation (SNP) | VAF 48/241 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV50043792; called by muse, mutect2, varscan2
- HOXC11 | c.392A>G p.H131R | Missense Mutation (SNP) | VAF 51/276 reads (18%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.636); catalogued as COSV54532251; called by muse, mutect2, varscan2
- HUWE1 | c.11172G>T p.L3724F | Missense Mutation (SNP) | VAF 90/282 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV53363274; called by muse, mutect2, varscan2
- IFT172 | c.2025C>T p.G675= | Splice Region (SNP) | VAF 22/290 reads (8%) | catalogued as rs762659921; ClinVar: likely benign; called by muse, mutect2
- IRAG1 | c.2605C>A p.L869M | Missense Mutation (SNP) | VAF 56/726 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70212290; called by muse, mutect2
- ITPR3 | c.528+2T>A p.X176_splice | Splice Site (SNP) | VAF 23/99 reads (23%) | catalogued as COSV65413687; called by muse, mutect2, varscan2
- KCNJ3 | c.973C>A p.H325N | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as COSV54538092; called by muse, mutect2, varscan2
- KIAA1549 | c.2855C>A p.P952H | Missense Mutation (SNP) | VAF 71/448 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54311802; called by muse, mutect2, varscan2
- KIF22 | c.151C>T p.R51W | Missense Mutation (SNP) | VAF 25/156 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142818922; called by muse, mutect2, varscan2
- KLHL32 | c.1109G>C p.R370P | Missense Mutation (SNP) | VAF 49/229 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65110624; called by muse, mutect2, varscan2
- LEPR | c.1106G>T p.W369L | Missense Mutation (SNP) | VAF 97/489 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60764327; called by muse, mutect2, varscan2
- LILRA2 | c.1400T>A p.L467Q (on ENST00000391738 / NM_001130917.3; = p.L450Q on NM_006866.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/283 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99252873; called by muse, mutect2, varscan2
- MED13L | c.3155G>A p.R1052Q | Missense Mutation (SNP) | VAF 21/242 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.988); catalogued as rs977444793; called by muse, mutect2
- MMP26 | c.745C>A p.Q249K | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as rs777091753; called by muse, mutect2, varscan2
- MUC16 | c.28924G>A p.D9642N | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.19); catalogued as rs768259697, COSV104431824; called by muse, mutect2, varscan2
- MUC16 | c.1178C>A p.P393Q | Missense Mutation (SNP) | VAF 48/283 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.455); catalogued as COSV67449366; called by muse, mutect2, varscan2
- MUC17 | c.5254A>G p.T1752A | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as rs1173774850; called by muse, mutect2, varscan2
- MUC5AC | c.1777G>T p.A593S | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0.01); catalogued as COSV62254286; called by muse, mutect2, varscan2
- MYO7A | c.1946G>A p.R649Q | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1308203959, COSV101289165; called by muse, mutect2
- MYOM3 | c.1018G>C p.E340Q | Missense Mutation (SNP) | VAF 33/198 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100293507; called by muse, mutect2, varscan2
- NALCN | c.1972A>G p.I658V | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT tolerated (0.85); PolyPhen benign (0.054); catalogued as rs779046867; called by muse, mutect2, varscan2
- NCKAP1L | c.2605-2A>G p.X869_splice | Splice Site (SNP) | VAF 35/231 reads (15%) | catalogued as rs372042504; called by muse, mutect2, varscan2
- NOTCH1 | c.4461G>A p.W1487* | Nonsense Mutation (SNP) | VAF 97/475 reads (20%) | catalogued as COSV53031789, COSV53078816; called by muse, mutect2, varscan2
- NUP43 | c.639-1G>C p.X213_splice | Splice Site (SNP) | VAF 22/103 reads (21%) | catalogued as COSV61189856; called by muse, mutect2, varscan2
- NXPH1 | c.491C>G p.S164C | Missense Mutation (SNP) | VAF 65/498 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68314065; called by muse, mutect2, varscan2
- OR10J3 | c.256C>A p.L86I | Missense Mutation (SNP) | VAF 60/464 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100171539, COSV59954043; called by muse, mutect2, varscan2
- OR10Q1 | c.553G>T p.D185Y | Missense Mutation (SNP) | VAF 66/398 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57470128; called by muse, mutect2, varscan2
- OR1N1 | c.266C>A p.T89N | Missense Mutation (SNP) | VAF 62/274 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1329625041; called by muse, mutect2, varscan2
- OR2G2 | c.340G>T p.E114* | Nonsense Mutation (SNP) | VAF 16/188 reads (9%) | catalogued as COSV60740985; called by muse, mutect2
- OR4D11 | c.482C>A p.S161Y | Missense Mutation (SNP) | VAF 52/395 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.021); catalogued as COSV57585924; called by muse, mutect2, varscan2
- OR4P4 | c.871G>C p.E291Q | Missense Mutation (SNP) | VAF 40/201 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV58921174; called by muse, mutect2, varscan2
- OR51E2 | c.716C>A p.T239N | Missense Mutation (SNP) | VAF 61/368 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as rs765016110; called by muse, varscan2
- OR51E2 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 53/310 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.121); catalogued as rs754309213; called by muse, varscan2
- OTOG | c.1879G>T p.V627L | Missense Mutation (SNP) | VAF 43/297 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV68039891; called by muse, mutect2, varscan2
- PCDHGB1 | c.2209C>T p.P737S | Missense Mutation (SNP) | VAF 107/513 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as rs1561503431; called by muse, mutect2, varscan2
- PERM1 | c.1222C>T p.H408Y | Missense Mutation (SNP) | VAF 78/336 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.491); catalogued as COSV58024068; called by muse, mutect2, varscan2
- PROS1 | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 41/589 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as rs772677117, COSV67776359; called by muse, mutect2
- PRPF6 | c.92G>T p.R31L | Missense Mutation (SNP) | VAF 44/244 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53865249; called by muse, mutect2, varscan2
- PSG1 | c.567G>T p.M189I | Missense Mutation (SNP) | VAF 87/502 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as COSV54953206; called by muse, mutect2, varscan2
- PTCHD4 | c.950G>A p.R317Q | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.095); catalogued as rs562179323, COSV59790140; called by muse, varscan2
- PXDNL | c.3508G>T p.D1170Y | Missense Mutation (SNP) | VAF 57/225 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62496302; called by muse, mutect2, varscan2
- RHOH | c.499G>C p.V167L | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV67805884; called by muse, mutect2, varscan2
- RIMS1 | c.3713C>A p.A1238E | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV53456477; called by muse, mutect2
- SBK1 | c.854C>T p.T285I | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV59396130; called by muse, mutect2, varscan2
- SCN1A | c.278T>C p.L93S | Missense Mutation (SNP) | VAF 22/277 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CD067204, CM1513852; called by muse, mutect2
- SERPINB3 | c.1046T>C p.V349A | Missense Mutation (SNP) | VAF 38/303 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.276); catalogued as rs1353255074; called by muse, mutect2, varscan2
- SLC25A13 | c.730A>T p.R244W | Missense Mutation (SNP) | VAF 101/627 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.353); catalogued as COSV99673179; called by muse, mutect2, varscan2
- SP140 | c.2581C>A p.Q861K | Missense Mutation (SNP) | VAF 34/396 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as COSV59450271; called by muse, mutect2
- SPATA48 | c.822G>T p.Q274H | Missense Mutation (SNP) | VAF 43/222 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as COSV51665679; called by muse, mutect2, varscan2
- STAB2 | c.1496A>G p.H499R | Missense Mutation (SNP) | VAF 26/277 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101185672; called by muse, mutect2
- STK32B | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375561881; called by muse, mutect2, varscan2
- TENM3 | c.6592C>A p.R2198S | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.972); catalogued as COSV69315290; called by muse, mutect2, varscan2
- TMED7 | c.51G>T p.W17C | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs775673404; called by muse, mutect2, varscan2
- TMEM235 | c.242A>G p.D81G | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs945431407; called by muse, mutect2, varscan2
- TMX4 | c.362G>C p.R121P | Missense Mutation (SNP) | VAF 51/374 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV55680513; called by muse, mutect2, varscan2
- TNS1 | c.1919G>C p.R640P | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50713619; called by muse, mutect2, varscan2
- TP53 | c.892del p.E298Sfs*47 | Frame Shift Del (DEL) | VAF 183/667 reads (27%) | catalogued as CM031387, COSV52661551, COSV52761493, COSV53353479, COSV53790595; called by mutect2, pindel, varscan2
- TRIM46 | c.1628G>A p.R543Q | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.259); catalogued as rs1444724249; called by muse, varscan2
- TRIML1 | c.421G>T p.E141* | Nonsense Mutation (SNP) | VAF 43/263 reads (16%) | catalogued as COSV60195983; called by muse, mutect2, varscan2
- TTN | c.2486G>A p.G829E (on ENST00000591111; = p.G783E on NM_003319.4) | Missense Mutation (SNP) | VAF 51/391 reads (13%) | PolyPhen benign (0.288); catalogued as COSV100636356, COSV60298022; called by muse, mutect2, varscan2
- UNC80 | c.3491C>A p.P1164H | Missense Mutation (SNP) | VAF 33/232 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as COSV55904489; called by muse, mutect2, varscan2
- UNCX | c.512G>A p.G171E | Missense Mutation (SNP) | VAF 36/380 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1446772847; called by muse, mutect2
- WASL | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 77/357 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1259802862, COSV56133561, COSV99771531; called by muse, mutect2, varscan2
- WNT5B | c.284G>T p.S95I | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV60198961; called by muse, mutect2, varscan2
- XKR4 | c.410del p.Y137Sfs*140 | Frame Shift Del (DEL) | VAF 26/218 reads (12%) | catalogued as COSV59327869; called by mutect2, pindel, varscan2
- ZBTB10 | c.97G>C p.G33R | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.545); catalogued as rs1326955710; called by muse, mutect2
- ZBTB49 | c.682G>T p.A228S | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.87); PolyPhen benign (0.011); catalogued as COSV61926078; called by mutect2, varscan2
- ZDHHC11 | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 52/536 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.041); catalogued as rs369832076; called by muse, mutect2
- ZDHHC4 | c.117+1G>T p.X39_splice | Splice Site (SNP) | VAF 36/235 reads (15%) | catalogued as rs1409351882; called by muse, varscan2
- ZFAND5 | c.-12A>G | Splice Region (SNP) | VAF 38/161 reads (24%) | catalogued as rs1214862513; called by muse, mutect2, varscan2
- ZFHX4 | c.3447G>T p.E1149D | Missense Mutation (SNP) | VAF 89/333 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.018); catalogued as rs1250374638; called by muse, mutect2, varscan2
- ZFHX4 | c.6598A>G p.I2200V | Missense Mutation (SNP) | VAF 36/411 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.08); catalogued as COSV51472958; called by muse, mutect2
- ZKSCAN2 | c.1294G>T p.A432S | Missense Mutation (SNP) | VAF 53/255 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as rs1259850847; called by muse, mutect2, varscan2
- ZNF532 | c.3377A>G p.N1126S | Missense Mutation (SNP) | VAF 66/433 reads (15%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs1420235889; called by muse, mutect2, varscan2
- ZNF705A | c.869G>A p.G290E | Missense Mutation (SNP) | VAF 25/238 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as COSV100828346; called by muse, mutect2, varscan2
- ZNF831 | c.2488C>A p.L830M | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.081); catalogued as COSV100925757; called by muse, mutect2, varscan2
- ZNF878 | c.253A>T p.T85S | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs377108052; called by muse, varscan2
- ZP1 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.021); catalogued as COSV53923968; called by muse, mutect2, varscan2
- ABCA10 | c.4131A>C p.Q1377H | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ABCC12 | c.2939A>G p.E980G | Missense Mutation (SNP) | VAF 16/235 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- ADAM33 | c.98-2A>T p.X33_splice | Splice Site (SNP) | VAF 44/215 reads (20%) | called by muse, mutect2, varscan2
- ADAMTS17 | c.1985A>T p.E662V | Missense Mutation (SNP) | VAF 54/393 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- ADAMTS6 | c.2766G>T p.R922S | Missense Mutation (SNP) | VAF 80/452 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ADAMTSL3 | c.1674G>T p.E558D | Missense Mutation (SNP) | VAF 58/346 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ADAT2 | c.555_561del p.K185Nfs*18 | Frame Shift Del (DEL) | VAF 22/241 reads (9%) | called by mutect2, pindel
- ADGRV1 | c.3899T>A p.I1300K | Missense Mutation (SNP) | VAF 70/434 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2
- ADGRV1 | c.3901G>A p.D1301N | Missense Mutation (SNP) | VAF 70/423 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AJAP1 | c.52G>T p.G18C | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- AKR1D1 | c.413del p.G138Afs*26 | Frame Shift Del (DEL) | VAF 37/356 reads (10%) | called by pindel, varscan2
- ANHX | c.401G>A p.C134Y | Missense Mutation (SNP) | VAF 37/182 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ANK2 | c.2349T>A p.H783Q | Missense Mutation (SNP) | VAF 108/691 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ANKRD33B | c.753C>G p.C251W | Missense Mutation (SNP) | VAF 41/355 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- ANO4 | c.23-2A>G p.X8_splice | Splice Site (SNP) | VAF 36/176 reads (20%) | called by muse, mutect2
- ANO5 | c.1332+1G>T p.X444_splice | Splice Site (SNP) | VAF 57/453 reads (13%) | called by muse, mutect2, varscan2
- ATP10A | c.2926G>T p.G976W | Missense Mutation (SNP) | VAF 70/424 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP6V1H | c.654G>A p.W218* | Nonsense Mutation (SNP) | VAF 58/348 reads (17%) | called by muse, mutect2, varscan2
- ATRAID | c.89del p.G30Efs*84 | Frame Shift Del (DEL) | VAF 50/281 reads (18%) | called by mutect2, pindel, varscan2
- ATRNL1 | c.3254G>C p.G1085A | Missense Mutation (SNP) | VAF 72/201 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BMP10 | c.773A>G p.D258G | Missense Mutation (SNP) | VAF 42/263 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- BTBD18 | c.87G>C p.Q29H | Missense Mutation (SNP) | VAF 12/185 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2
- C1orf127 | c.5G>T p.W2L | Missense Mutation (SNP) | VAF 35/284 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- C20orf194 | c.3529C>T p.P1177S | Missense Mutation (SNP) | VAF 21/207 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C5orf34 | c.1100C>T p.A367V | Missense Mutation (SNP) | VAF 40/470 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2
- CACNG4 | c.125A>T p.N42I | Missense Mutation (SNP) | VAF 77/529 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAMTA1 | c.2729C>G p.S910* | Nonsense Mutation (SNP) | VAF 48/316 reads (15%) | called by muse, mutect2, varscan2
- CAPN9 | c.511G>T p.A171S | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CARD11 | c.1150C>T p.H384Y | Missense Mutation (SNP) | VAF 26/317 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- CARF | c.77A>G p.E26G | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- CCHCR1 | c.1799-3C>A | Splice Region (SNP) | VAF 39/218 reads (18%) | called by muse, mutect2, varscan2
- CDC42BPB | c.2006G>A p.G669E | Missense Mutation (SNP) | VAF 34/211 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0.017); called by muse, mutect2
- CELSR2 | c.936G>T p.R312S | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CEP72 | c.1055G>A p.G352D | Missense Mutation (SNP) | VAF 39/560 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.058); called by muse, mutect2
- CFAP47 | c.4438G>A p.E1480K | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- CHD7 | c.7513G>T p.G2505* | Nonsense Mutation (SNP) | VAF 23/107 reads (21%) | called by muse, varscan2
- CHRD | c.2767G>C p.G923R | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT tolerated (0.73); PolyPhen benign (0.001); called by muse, mutect2
- CHRNA1 | c.755T>C p.M252T (on ENST00000261007 / NM_001039523.3; = p.M227T on NM_000079.4) | Missense Mutation (SNP) | VAF 40/495 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.158); called by muse, mutect2
- CNTNAP2 | c.3915G>T p.E1305D | Missense Mutation (SNP) | VAF 65/342 reads (19%) | SIFT tolerated (0.9); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- COG5 | c.374A>G p.Y125C | Missense Mutation (SNP) | VAF 119/639 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.362); called by muse, mutect2, varscan2
- COL11A2 | c.3184G>A p.D1062N (on ENST00000341947 / NM_080680.3; = p.D955N on NM_080679.2) | Missense Mutation (SNP) | VAF 96/634 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COL25A1 | c.1513C>T p.P505S | Missense Mutation (SNP) | VAF 44/262 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL4A3 | c.598C>A p.P200T | Missense Mutation (SNP) | VAF 57/303 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL4A4 | c.2815G>T p.G939C | Missense Mutation (SNP) | VAF 52/522 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL6A1 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 32/203 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CPXM1 | c.1496G>T p.G499V | Missense Mutation (SNP) | VAF 42/215 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRB1 | c.1555C>A p.P519T | Missense Mutation (SNP) | VAF 64/388 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- CRISPLD1 | c.732del p.S245Qfs*15 | Frame Shift Del (DEL) | VAF 54/178 reads (30%) | called by mutect2, pindel, varscan2
- CTBP2 | c.1130A>G p.H377R | Missense Mutation (SNP) | VAF 39/296 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- CTCFL | c.1396G>A p.V466I | Missense Mutation (SNP) | VAF 34/415 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.014); called by muse, mutect2
- CTR9 | c.2068A>T p.I690F | Missense Mutation (SNP) | VAF 48/218 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- CYP4A22 | c.730A>T p.S244C | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- CYTH1 | c.956A>T p.K319I | Missense Mutation (SNP) | VAF 90/540 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- CYTH3 | c.979T>A p.C327S (on ENST00000396741; = p.C326S on NM_004227.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- DISP3 | c.872C>A p.T291N | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DMXL1 | c.2426G>T p.R809M | Missense Mutation (SNP) | VAF 57/303 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- DNAH6 | c.3697C>A p.P1233T | Missense Mutation (SNP) | VAF 116/758 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH6 | c.9316A>T p.S3106C | Missense Mutation (SNP) | VAF 38/253 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- DOCK6 | c.4192A>G p.I1398V | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2
- DPP6 | c.45C>A p.N15K | Missense Mutation (SNP) | VAF 32/220 reads (15%) | SIFT tolerated (0.9); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- DPP6 | c.1475C>G p.A492G (on ENST00000377770 / NM_001364500.2; = p.A430G on NM_001936.5) | Missense Mutation (SNP) | VAF 24/264 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, mutect2
- DSCAML1 | c.1361C>T p.T454I (on ENST00000321322; = p.T394I on NM_020693.4) | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.16); called by muse, mutect2
- DZIP3 | c.1249C>T p.P417S | Missense Mutation (SNP) | VAF 15/298 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.879); called by muse, mutect2
- EIF3E | c.1178T>C p.M393T | Missense Mutation (SNP) | VAF 36/193 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- EPHX3 | c.779A>C p.E260A | Missense Mutation (SNP) | VAF 27/218 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- ERN1 | c.2012A>T p.Q671L | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ERVV-2 | c.1054C>A p.L352I | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- FAM160A1 | c.404A>T p.H135L | Missense Mutation (SNP) | VAF 62/408 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- FAM71A | c.296C>A p.A99D | Missense Mutation (SNP) | VAF 42/301 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- FAM78B | c.192G>T p.E64D | Missense Mutation (SNP) | VAF 39/397 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- FAM83B | c.2018C>A p.A673D | Missense Mutation (SNP) | VAF 39/217 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- FAT1 | c.9997C>A p.P3333T | Missense Mutation (SNP) | VAF 82/346 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- FAT3 | c.5523T>A p.H1841Q | Missense Mutation (SNP) | VAF 34/211 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- FAT3 | c.13249G>T p.D4417Y | Missense Mutation (SNP) | VAF 45/213 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- FBN2 | c.4717+1G>T p.X1573_splice | Splice Site (SNP) | VAF 84/417 reads (20%) | called by muse, mutect2, varscan2
- FBN3 | c.4808G>T p.C1603F | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- FCGBP | c.1516G>T p.D506Y | Missense Mutation (SNP) | VAF 19/242 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.669); called by muse, mutect2
- FLT1 | c.52C>G p.L18V | Missense Mutation (SNP) | VAF 34/396 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2
- FNDC3A | c.2357G>A p.G786E (on ENST00000492622 / NM_001079673.2; = p.G730E on NM_014923.5) | Missense Mutation (SNP) | VAF 40/213 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- FOXF1 | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- FOXK2 | c.1133G>C p.G378A | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- FOXP2 | c.1616C>T p.A539V | Missense Mutation (SNP) | VAF 97/561 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- FRMD4A | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 39/261 reads (15%) | called by muse, mutect2, varscan2
- FSCN3 | c.1208G>A p.G403D | Missense Mutation (SNP) | VAF 37/231 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- FZR1 | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- GANAB | c.1180C>A p.L394I | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- GARRE1 | c.597G>C p.E199D | Missense Mutation (SNP) | VAF 78/473 reads (16%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GLIS1 | c.1162G>T p.G388C | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- GPR135 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GPR39 | c.139G>T p.G47W | Missense Mutation (SNP) | VAF 111/791 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRB14 | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 34/259 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- GTF2H3 | c.650T>C p.V217A | Missense Mutation (SNP) | VAF 27/535 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.67); called by muse, mutect2
- HDAC11 | c.353C>A p.T118K | Missense Mutation (SNP) | VAF 37/152 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- HDDC3 | c.276C>G p.D92E | Missense Mutation (SNP) | VAF 58/405 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- HECTD3 | c.74_79del p.E25_A26del | In Frame Del (DEL) | VAF 7/67 reads (10%) | called by mutect2, pindel
- HERC6 | c.938G>A p.G313D | Missense Mutation (SNP) | VAF 41/196 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HLA-F | c.497G>T p.R166L | Missense Mutation (SNP) | VAF 80/571 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- HMGN1 | c.127-2A>T p.X43_splice | Splice Site (SNP) | VAF 49/286 reads (17%) | called by muse, mutect2, varscan2
- HOXC6 | c.71T>A p.V24D | Missense Mutation (SNP) | VAF 40/254 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- HRH3 | c.1017G>T p.M339I | Missense Mutation (SNP) | VAF 24/234 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.015); called by muse, mutect2
- HSD17B4 | c.1174G>A p.G392R (on ENST00000414835 / NM_001199291.3; = p.G367R on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 121/570 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- HSPG2 | c.12262G>A p.D4088N | Missense Mutation (SNP) | VAF 55/302 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HYDIN | c.1974G>T p.R658S | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.085); called by mutect2, varscan2
- IDO1 | c.483A>T p.K161N | Missense Mutation (SNP) | VAF 49/1076 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2
- IFIT1B | c.514C>A p.P172T | Missense Mutation (SNP) | VAF 49/138 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- IGSF10 | c.3350C>G p.P1117R | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.174); called by muse, mutect2
- IL1RAPL2 | c.2040del p.F681Lfs*14 | Frame Shift Del (DEL) | VAF 13/48 reads (27%) | called by mutect2, pindel, varscan2
- IRS2 | c.1586C>A p.P529Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2
- ITPRID1 | c.1114C>A p.L372I | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- ITPRID1 | c.3124G>T p.V1042F | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- KANSL3 | c.1086+2T>G p.X362_splice | Splice Site (SNP) | VAF 46/288 reads (16%) | called by muse, mutect2, varscan2
- KATNAL2 | c.216del p.M73Wfs*9 | Frame Shift Del (DEL) | VAF 25/178 reads (14%) | called by mutect2, pindel, varscan2
- KCNC2 | c.1468C>T p.P490S | Missense Mutation (SNP) | VAF 53/307 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- KCNH8 | c.2519C>A p.P840H | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- KIAA0100 | c.133G>T p.G45C | Missense Mutation (SNP) | VAF 49/218 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- KIAA0232 | c.2539G>T p.D847Y | Missense Mutation (SNP) | VAF 49/335 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- KIAA0408 | c.1958C>A p.P653H | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA1217 | c.2734C>T p.H912Y | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF13A | c.1288del p.S430Afs*20 | Frame Shift Del (DEL) | VAF 23/181 reads (13%) | called by mutect2, pindel, varscan2
- KIF14 | c.2646A>T p.L882F | Missense Mutation (SNP) | VAF 39/304 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLF1 | c.763C>A p.P255T | Missense Mutation (SNP) | VAF 86/556 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KNL1 | c.3968G>T p.G1323V (on ENST00000346991 / NM_170589.5; = p.G1297V on NM_144508.5) | Missense Mutation (SNP) | VAF 37/180 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- KRBA1 | c.1117G>C p.E373Q | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0.012); called by muse, varscan2
- KRI1 | c.1670C>T p.T557I | Missense Mutation (SNP) | VAF 42/280 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRTAP2-3 | c.8G>T p.G3V | Missense Mutation (SNP) | VAF 38/317 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LARP1B | c.1908G>T p.K636N | Missense Mutation (SNP) | VAF 23/191 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- LRIG3 | c.1898A>T p.Q633L | Missense Mutation (SNP) | VAF 41/243 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRP1B | c.1395A>T p.R465S | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.419); called by muse, mutect2
- LRP4 | c.3806A>G p.D1269G | Missense Mutation (SNP) | VAF 64/495 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC4B | c.1901C>T p.A634V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- LRRC9 | c.2431G>T p.G811C | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LSMEM2 | c.310C>A p.L104M | Missense Mutation (SNP) | VAF 71/227 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- MAN1A1 | c.1291C>A p.L431M | Missense Mutation (SNP) | VAF 37/248 reads (15%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- MAPKAP1 | c.793G>A p.V265I | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- MCM3AP | c.1492A>T p.M498L | Missense Mutation (SNP) | VAF 44/242 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- MCRIP2 | c.5A>T p.Y2F | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- MED24 | c.1049A>T p.K350I | Missense Mutation (SNP) | VAF 31/167 reads (19%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MEF2B | c.467G>T p.G156V | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MEGF10 | c.1009G>T p.G337C | Missense Mutation (SNP) | VAF 78/411 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MEI1 | c.1417T>C p.S473P | Missense Mutation (SNP) | VAF 16/291 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.074); called by muse, mutect2
- MFSD13A | c.305T>A p.L102Q | Missense Mutation (SNP) | VAF 45/166 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- MIA2 | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 23/201 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- MUC16 | c.31165G>T p.G10389C | Missense Mutation (SNP) | VAF 26/229 reads (11%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- MYH8 | c.224G>A p.R75K | Missense Mutation (SNP) | VAF 147/451 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYH9 | c.3647A>G p.E1216G | Missense Mutation (SNP) | VAF 28/408 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- MYT1 | c.1196G>A p.G399D | Missense Mutation (SNP) | VAF 35/218 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- NALCN | c.3691T>A p.W1231R | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- NCAPG | c.2768-1G>T p.X923_splice | Splice Site (SNP) | VAF 15/66 reads (23%) | called by muse, mutect2, varscan2
- NCKAP5 | c.923A>T p.N308I | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, varscan2
- NCKAP5L | c.3041A>T p.Q1014L | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- NCOR2 | c.5390A>G p.E1797G | Missense Mutation (SNP) | VAF 37/238 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NEO1 | c.3985G>T p.G1329C | Missense Mutation (SNP) | VAF 82/525 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- NIBAN3 | c.1054G>T p.V352L | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NLRP5 | c.1834G>T p.V612F | Missense Mutation (SNP) | VAF 54/300 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NLRP9 | c.2819C>G p.P940R | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- NOD2 | c.2063del p.G688Afs*75 | Frame Shift Del (DEL) | VAF 18/110 reads (16%) | called by mutect2, pindel
- NOVA1 | c.1087G>T p.A363S | Missense Mutation (SNP) | VAF 36/187 reads (19%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- NOVA1 | c.1086G>T p.L362F | Missense Mutation (SNP) | VAF 36/188 reads (19%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NPAS4 | c.884A>G p.Y295C | Missense Mutation (SNP) | VAF 55/364 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- NR2F2 | c.1162G>T p.G388C | Missense Mutation (SNP) | VAF 73/488 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NRG2 | c.1588A>T p.T530S | Missense Mutation (SNP) | VAF 69/318 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- NSFL1C | c.517A>G p.R173G | Missense Mutation (SNP) | VAF 22/322 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.046); called by muse, mutect2
- NSMAF | c.64T>C p.S22P | Missense Mutation (SNP) | VAF 82/487 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- OR2L2 | c.857C>A p.P286H | Missense Mutation (SNP) | VAF 37/181 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR2L5 | c.340C>A p.L114M | Missense Mutation (SNP) | VAF 27/470 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- OR4S1 | c.350C>A p.A117D | Missense Mutation (SNP) | VAF 26/175 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR51Q1 | c.619C>T p.L207F | Missense Mutation (SNP) | VAF 31/316 reads (10%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.664); called by muse, mutect2
- OR6N1 | c.145G>C p.V49L | Missense Mutation (SNP) | VAF 40/339 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- OTOG | c.2723G>C p.C908S | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- OTOG | c.7880C>A p.A2627D | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PAGR1 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 59/359 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- PAN2 | c.2507G>T p.W836L (on ENST00000425394 / NM_001127460.3; = p.W832L on NM_014871.5) | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, varscan2
- PATJ | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- PAX7 | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDH10 | c.1109G>T p.G370V | Missense Mutation (SNP) | VAF 36/237 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- PDZD2 | c.2879G>C p.R960T | Missense Mutation (SNP) | VAF 204/452 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- PER2 | c.2456C>T p.A819V | Missense Mutation (SNP) | VAF 25/239 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- PGLYRP3 | c.171C>A p.C57* | Nonsense Mutation (SNP) | VAF 58/347 reads (17%) | called by muse, mutect2, varscan2
- PHACTR3 | c.716C>A p.P239H | Missense Mutation (SNP) | VAF 70/237 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PI15 | c.95del p.P32Rfs*13 | Frame Shift Del (DEL) | VAF 84/865 reads (10%) | called by mutect2, pindel
- PIKFYVE | c.430G>T p.G144W | Missense Mutation (SNP) | VAF 54/300 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PITPNM2 | c.575A>T p.K192M | Missense Mutation (SNP) | VAF 36/275 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PKD1L3 | c.2911A>G p.I971V | Missense Mutation (SNP) | VAF 42/217 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- POLQ | c.5897A>T p.D1966V | Missense Mutation (SNP) | VAF 15/238 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- PPP4R3C | c.568G>C p.G190R | Missense Mutation (SNP) | VAF 41/152 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- PRKACG | c.532C>A p.Q178K | Missense Mutation (SNP) | VAF 50/260 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRKCG | c.1723C>A p.P575T | Missense Mutation (SNP) | VAF 47/280 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PROSER3 | c.154C>G p.P52A | Missense Mutation (SNP) | VAF 37/340 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- PRSS16 | c.598del p.H200Ifs*30 | Frame Shift Del (DEL) | VAF 61/338 reads (18%) | called by mutect2, pindel, varscan2
- PTGDR | c.687C>G p.H229Q | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- PTPRF | c.4603G>T p.A1535S | Missense Mutation (SNP) | VAF 32/211 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- QRFPR | c.112C>A p.P38T | Missense Mutation (SNP) | VAF 39/250 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- QRICH2 | c.3966A>G p.K1322= | Splice Region (SNP) | VAF 29/148 reads (20%) | called by muse, mutect2, varscan2
- RELN | c.4056A>C p.R1352S | Missense Mutation (SNP) | VAF 58/816 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by muse, mutect2
- REX1BD | c.105C>A p.D35E | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- RHPN1 | c.683G>T p.G228V | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RNF26 | c.135C>G p.N45K | Missense Mutation (SNP) | VAF 40/483 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.036); called by muse, mutect2
- RNF34 | c.28G>T p.A10S | Missense Mutation (SNP) | VAF 55/302 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RPS6KA6 | c.545T>A p.L182Q | Missense Mutation (SNP) | VAF 68/240 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RYR2 | c.12109C>A p.P4037T | Missense Mutation (SNP) | VAF 81/508 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- RYR3 | c.3875del p.M1292Sfs*57 | Frame Shift Del (DEL) | VAF 20/182 reads (11%) | called by mutect2, pindel, varscan2
- SALL3 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- SELP | c.2408-1G>T p.X803_splice | Splice Site (SNP) | VAF 20/132 reads (15%) | called by muse, mutect2, varscan2
- SERINC1 | c.341G>T p.S114I | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, varscan2
- SERPINB12 | c.943C>G p.Q315E | Missense Mutation (SNP) | VAF 49/290 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- SFMBT2 | c.696G>A p.W232* | Nonsense Mutation (SNP) | VAF 91/396 reads (23%) | called by muse, mutect2, varscan2
- SGIP1 | c.2402G>T p.C801F | Missense Mutation (SNP) | VAF 46/244 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, varscan2
- SGPP2 | c.288G>C p.L96F | Missense Mutation (SNP) | VAF 10/272 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.197); called by muse, mutect2
- SIN3B | c.304G>T p.A102S | Missense Mutation (SNP) | VAF 38/306 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- SLAIN1 | c.149C>A p.A50E | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- SLC35F1 | c.1087G>C p.D363H | Missense Mutation (SNP) | VAF 69/477 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SLC35G3 | c.534G>T p.W178C | Missense Mutation (SNP) | VAF 46/765 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.221); called by muse, mutect2
- SLC39A3 | c.419del p.G140Afs*18 | Frame Shift Del (DEL) | VAF 26/127 reads (20%) | called by mutect2, pindel, varscan2
- SPATA5 | c.1385G>C p.R462T | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- STARD13 | c.901A>T p.M301L (on ENST00000336934 / NM_001243476.3; = p.M183L on NM_052851.3) | Missense Mutation (SNP) | VAF 77/454 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- STT3A | c.1431G>C p.W477C | Missense Mutation (SNP) | VAF 22/288 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- STXBP1 | c.575G>T p.R192L | Missense Mutation (SNP) | VAF 50/346 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SUGCT | c.558G>T p.M186I | Missense Mutation (SNP) | VAF 37/200 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- SUPT20HL1 | c.893G>T p.C298F | Missense Mutation (SNP) | VAF 98/330 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- SUV39H1 | c.331G>T p.D111Y | Missense Mutation (SNP) | VAF 70/192 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SYNE1 | c.6514G>C p.E2172Q (on ENST00000367255 / NM_182961.4; = p.E2179Q on NM_033071.3) | Missense Mutation (SNP) | VAF 30/356 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.166); called by muse, mutect2
- SYNE1 | c.5782G>A p.G1928S (on ENST00000367255 / NM_182961.4; = p.G1935S on NM_033071.3) | Missense Mutation (SNP) | VAF 143/851 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TAF4 | c.604G>T p.A202S | Missense Mutation (SNP) | VAF 27/189 reads (14%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- TAP1 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 168/896 reads (19%) | called by muse, varscan2
- TCFL5 | c.482G>A p.G161D | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.046); called by muse, varscan2
- TET3 | c.2722G>T p.V908L | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- THSD7A | c.4468A>C p.T1490P | Missense Mutation (SNP) | VAF 71/537 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TM6SF2 | c.269T>A p.V90E | Missense Mutation (SNP) | VAF 46/273 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM116 | c.523G>A p.V175I | Missense Mutation (SNP) | VAF 32/365 reads (9%) | SIFT tolerated (0.9); PolyPhen benign (0.015); called by muse, mutect2
- TMEM131 | c.309del p.N104Ifs*40 | Frame Shift Del (DEL) | VAF 37/317 reads (12%) | called by mutect2, pindel, varscan2
- TMEM211 | c.515G>T p.W172L (on ENST00000423535; = p.W101L on NM_001001663.3) | Missense Mutation (SNP) | VAF 22/374 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.422); called by muse, mutect2
- TMPRSS15 | c.916A>T p.I306F | Missense Mutation (SNP) | VAF 29/275 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TMPRSS9 | c.3265C>A p.Q1089K (on ENST00000648592; = p.Q1055K on NM_182973.2) | Missense Mutation (SNP) | VAF 48/303 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- TNIP3 | c.574G>T p.E192* | Nonsense Mutation (SNP) | VAF 33/218 reads (15%) | called by muse, mutect2, varscan2
- TOGARAM1 | c.736G>T p.D246Y | Missense Mutation (SNP) | VAF 33/176 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TOR1AIP1 | c.721G>T p.D241Y | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- TRBJ2-7 | c.41C>A p.T14K | Missense Mutation (SNP) | VAF 36/207 reads (17%) | called by muse, mutect2, varscan2
- TRIM47 | c.509T>A p.L170Q | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- TRIM51GP | c.1156G>T p.D386Y | Missense Mutation (SNP) | VAF 62/498 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- TRIML1 | c.420G>T p.Q140H | Missense Mutation (SNP) | VAF 41/257 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRIOBP | c.4592C>G p.S1531C | Missense Mutation (SNP) | VAF 106/407 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- TTN | c.23136del p.K7713Nfs*13 (on ENST00000591111; = p.K6786Nfs*13 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 54/410 reads (13%) | called by mutect2, pindel, varscan2
- TTN | c.6790+5T>A | Splice Region (SNP) | VAF 46/282 reads (16%) | called by muse, varscan2
- TTN | c.6739G>A p.V2247I (on ENST00000591111; = p.V2201I on NM_003319.4) | Missense Mutation (SNP) | VAF 40/300 reads (13%) | PolyPhen benign (0.053); called by muse, varscan2
- TTYH3 | c.439G>T p.A147S | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); called by mutect2, varscan2
- TUT7 | c.3184T>A p.C1062S | Missense Mutation (SNP) | VAF 54/238 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- UBA6 | c.1428G>C p.L476F | Missense Mutation (SNP) | VAF 42/220 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UNC5D | c.1703A>T p.H568L | Missense Mutation (SNP) | VAF 44/207 reads (21%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- UNC80 | c.7780A>G p.N2594D | Missense Mutation (SNP) | VAF 23/312 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); called by muse, mutect2
- UNC93A | c.448G>T p.V150L | Missense Mutation (SNP) | VAF 71/549 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- UNCX | c.977T>A p.L326Q | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- USP42 | c.949C>A p.L317M | Missense Mutation (SNP) | VAF 42/231 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VNN3 | c.481T>C p.Y161H | Missense Mutation (SNP) | VAF 48/327 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- WDFY4 | c.8802G>T p.W2934C | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WDR19 | c.2697G>T p.L899F | Missense Mutation (SNP) | VAF 32/194 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- WNT9B | c.226G>T p.E76* | Nonsense Mutation (SNP) | VAF 31/208 reads (15%) | called by muse, mutect2, varscan2
- XIRP1 | c.2603G>T p.S868I | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- XIRP2 | c.5663G>T p.G1888V (on ENST00000628543; = p.G2063V on NM_152381.6) | Missense Mutation (SNP) | VAF 35/204 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- YIPF2 | c.946_947dup p.*317Pfs*35 | Frame Shift Ins (INS) | VAF 9/70 reads (13%) | called by mutect2, pindel
- ZACN | c.1027C>G p.P343A | Missense Mutation (SNP) | VAF 14/318 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- ZAN | c.5893A>T p.M1965L | Missense Mutation (SNP) | VAF 78/543 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZBTB7B | c.1531C>A p.P511T (on ENST00000292176; = p.P545T on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.066); called by muse, mutect2
- ZDBF2 | c.736del p.T246Lfs*19 | Frame Shift Del (DEL) | VAF 43/272 reads (16%) | called by mutect2, pindel, varscan2
- ZNF132 | c.17del p.P6Hfs*4 | Frame Shift Del (DEL) | VAF 36/181 reads (20%) | called by mutect2, pindel, varscan2
- ZNF205 | c.343C>A p.L115I | Missense Mutation (SNP) | VAF 42/324 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZNF304 | c.712C>T p.L238F | Missense Mutation (SNP) | VAF 35/195 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- ZNF420 | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2
- ZNF438 | c.502G>T p.E168* | Nonsense Mutation (SNP) | VAF 54/251 reads (22%) | called by muse, mutect2, varscan2
- ZNF469 | c.692G>T p.G231V | Missense Mutation (SNP) | VAF 22/456 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); called by muse, mutect2
- ZNF536 | c.3681del p.A1228Hfs*35 | Frame Shift Del (DEL) | VAF 11/97 reads (11%) | called by mutect2, varscan2
- ZNF577 | c.186A>T p.I62= | Splice Region (SNP) | VAF 20/116 reads (17%) | called by muse, mutect2, varscan2
- ZNF585A | c.2018A>G p.Q673R (on ENST00000292841 / NM_001288800.2; = p.Q618R on NM_152655.3) | Missense Mutation (SNP) | VAF 24/344 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.022); called by muse, mutect2
- ZNF717 | c.2290G>T p.G764W | Missense Mutation (SNP) | VAF 485/746 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF729 | c.2839G>A p.D947N | Missense Mutation (SNP) | VAF 33/232 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF792 | c.10G>T p.A4S | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- ZP4 | c.1574A>T p.Y525F | Missense Mutation (SNP) | VAF 44/216 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ZSCAN18 | c.1255G>T p.G419W | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZXDA | c.145G>T p.G49C | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- ADGB | c.2784C>G p.A928= | Silent (SNP) | VAF 46/213 reads (22%) | called by muse, mutect2, varscan2
- ADGRB3 | c.4389C>G p.P1463= | Silent (SNP) | VAF 26/133 reads (20%) | called by muse, mutect2, varscan2
- AKR1B1 | c.780G>T p.V260= | Silent (SNP) | VAF 56/785 reads (7%) | called by muse, mutect2
- APC2 | c.2622C>G p.L874= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV99279250; called by muse, varscan2
- ARID3B | c.408C>T p.P136= | Silent (SNP) | VAF 56/430 reads (13%) | catalogued as rs1186645780; called by muse, mutect2, varscan2
- ARPP21 | c.1284T>A p.P428= | Silent (SNP) | VAF 77/296 reads (26%) | called by muse, mutect2, varscan2
- ASXL3 | c.555A>G p.T185= | Silent (SNP) | VAF 16/228 reads (7%) | catalogued as rs1392720430; called by muse, mutect2
- BMP10 | c.1026C>A p.I342= | Silent (SNP) | VAF 41/199 reads (21%) | called by muse, mutect2, varscan2
- BPIFC | c.408C>T p.S136= | Silent (SNP) | VAF 33/161 reads (20%) | catalogued as rs200973548; called by muse, mutect2, varscan2
- C16orf78 | c.183A>G p.K61= | Silent (SNP) | VAF 37/200 reads (19%) | called by muse, mutect2, varscan2
- C1QTNF4 | c.678C>T p.P226= | Silent (SNP) | VAF 22/236 reads (9%) | catalogued as rs1344275879; called by muse, mutect2
- CBX5 | c.90G>T p.V30= | Silent (SNP) | VAF 55/369 reads (15%) | called by muse, mutect2, varscan2
- CCDC39 | c.1200T>A p.G400= | Silent (SNP) | VAF 24/73 reads (33%) | called by muse, varscan2
- CDH4 | c.1485C>T p.T495= | Silent (SNP) | VAF 42/560 reads (8%) | called by muse, mutect2
- CEP128 | c.2820G>A p.E940= | Silent (SNP) | VAF 34/185 reads (18%) | catalogued as COSV55370048, COSV55387192; called by muse, mutect2, varscan2
- CFLAR | c.174G>A p.L58= | Silent (SNP) | VAF 34/230 reads (15%) | called by muse, mutect2, varscan2
- CSF1 | c.957A>G p.Q319= | Silent (SNP) | VAF 30/420 reads (7%) | called by muse, mutect2
- CSMD3 | c.7821T>C p.S2607= (on ENST00000297405 / NM_001363185.1; = p.S2503= on NM_052900.3) | Silent (SNP) | VAF 25/242 reads (10%) | called by muse, mutect2, varscan2
- CXorf66 | c.753A>T p.L251= | Silent (SNP) | VAF 85/224 reads (38%) | called by muse, mutect2, varscan2
- DAAM2 | c.642G>A p.K214= | Silent (SNP) | VAF 60/380 reads (16%) | catalogued as COSV51332663; called by muse, mutect2, varscan2
- DAGLA | c.999G>T p.P333= | Silent (SNP) | VAF 28/178 reads (16%) | called by muse, mutect2, varscan2
- DCTN1 | c.2199C>T p.I733= | Silent (SNP) | VAF 115/946 reads (12%) | catalogued as rs1294852289; called by muse, mutect2, varscan2
- DDX21 | c.969A>T p.I323= | Silent (SNP) | VAF 41/212 reads (19%) | called by muse, mutect2, varscan2
- DHX58 | c.483C>A p.P161= | Silent (SNP) | VAF 34/218 reads (16%) | catalogued as COSV52425452; called by muse, mutect2, varscan2
- DNAH5 | c.9027C>A p.I3009= | Silent (SNP) | VAF 303/675 reads (45%) | called by muse, mutect2, varscan2
- DNAH5 | c.4647G>A p.K1549= | Silent (SNP) | VAF 32/460 reads (7%) | called by muse, mutect2
- DST | c.11721A>G p.A3907= (on ENST00000361203 / NM_001374722.1; = p.A1495= on NM_015548.5) | Silent (SNP) | VAF 35/175 reads (20%) | called by muse, mutect2, varscan2
- DYNC1I1 | c.279A>G p.P93= | Silent (SNP) | VAF 31/422 reads (7%) | catalogued as COSV61455344; called by muse, mutect2
- FAM205A | c.2943C>A p.S981= | Silent (SNP) | VAF 46/313 reads (15%) | called by muse, mutect2, varscan2
- FAM47A | c.1155C>T p.S385= | Silent (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
- FAM83D | c.981C>A p.G327= | Silent (SNP) | VAF 31/255 reads (12%) | called by muse, mutect2, varscan2
- FAT3 | c.4773G>T p.L1591= | Silent (SNP) | VAF 86/457 reads (19%) | called by muse, mutect2, varscan2
- FBLIM1 | c.81G>T p.A27= | Silent (SNP) | VAF 36/402 reads (9%) | called by muse, mutect2
- FLG | c.5595C>T p.S1865= | Silent (SNP) | VAF 54/467 reads (12%) | catalogued as COSV100910408, COSV64237437; called by muse, mutect2, varscan2
- FLNC | c.5481A>G p.A1827= | Silent (SNP) | VAF 35/503 reads (7%) | called by muse, mutect2
- FZD2 | c.888G>A p.A296= | Silent (SNP) | VAF 15/91 reads (16%) | catalogued as rs1410596031, COSV100190227; called by muse, mutect2, varscan2
- GMPS | c.1077A>G p.P359= | Silent (SNP) | VAF 106/278 reads (38%) | catalogued as COSV99903406; called by muse, mutect2, varscan2
- GPAT4 | c.888G>A p.K296= | Silent (SNP) | VAF 281/457 reads (61%) | called by muse, mutect2, varscan2
- GPR88 | c.828G>T p.R276= | Silent (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
- HCN1 | c.2541G>T p.S847= | Silent (SNP) | VAF 210/439 reads (48%) | catalogued as COSV57502512; called by muse, mutect2, varscan2
- HIVEP1 | c.6750C>T p.P2250= | Silent (SNP) | VAF 46/299 reads (15%) | called by muse, mutect2, varscan2
- HOXA7 | c.546C>A p.R182= | Silent (SNP) | VAF 88/552 reads (16%) | called by muse, mutect2, varscan2
- HUWE1 | c.12579G>T p.G4193= | Silent (SNP) | VAF 100/336 reads (30%) | called by muse, mutect2, varscan2
- IGHM | c.252A>G p.E84= | Silent (SNP) | VAF 107/795 reads (13%) | called by muse, mutect2, varscan2
- IPO5 | c.417A>T p.S139= | Silent (SNP) | VAF 80/383 reads (21%) | called by mutect2, varscan2
- IRF4 | c.1251T>A p.A417= | Silent (SNP) | VAF 124/380 reads (33%) | called by muse, mutect2, varscan2
- KBTBD8 | c.462G>T p.G154= | Silent (SNP) | VAF 59/202 reads (29%) | catalogued as COSV55131237; called by muse, mutect2, varscan2
- KCNC2 | c.417C>A p.A139= | Silent (SNP) | VAF 77/533 reads (14%) | catalogued as rs1379125165; called by muse, mutect2, varscan2
- KCNH6 | c.888C>G p.T296= | Silent (SNP) | VAF 59/308 reads (19%) | called by muse, mutect2, varscan2
- KDM4E | c.153C>G p.P51= | Silent (SNP) | VAF 54/333 reads (16%) | called by muse, mutect2, varscan2
- KIT | c.1578G>T p.L526= | Silent (SNP) | VAF 91/542 reads (17%) | called by muse, mutect2, varscan2
- KRTAP10-4 | c.492C>G p.V164= | Silent (SNP) | VAF 76/967 reads (8%) | catalogued as rs781915313; called by muse, mutect2
- LILRB1 | c.2097C>A p.A699= (on ENST00000427581; = p.A648= on NM_006669.6) | Silent (SNP) | VAF 14/91 reads (15%) | called by muse, mutect2
- LRP1B | c.12750C>A p.V4250= | Silent (SNP) | VAF 24/266 reads (9%) | called by muse, mutect2
- LSAMP | c.18C>A p.P6= | Silent (SNP) | VAF 44/136 reads (32%) | called by muse, mutect2, varscan2
- MAGI2 | c.204G>A p.E68= | Silent (SNP) | VAF 38/231 reads (16%) | called by muse, mutect2, varscan2
- MAP2 | c.1425C>A p.T475= | Silent (SNP) | VAF 34/272 reads (13%) | catalogued as COSV52314299; called by mutect2, varscan2
- MDN1 | c.3705G>A p.R1235= | Silent (SNP) | VAF 59/379 reads (16%) | catalogued as rs920738192, COSV65531733; called by muse, mutect2, varscan2
- METRNL | c.807C>T p.F269= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as rs138062461; called by muse, mutect2, varscan2
- MMS22L | c.2109A>G p.L703= | Silent (SNP) | VAF 36/244 reads (15%) | called by muse, mutect2, varscan2
- MPIG6B | c.725G>A p.*242= | Silent (SNP) | VAF 36/171 reads (21%) | catalogued as COSV101008104; called by muse, mutect2, varscan2
- MUC16 | c.37653C>A p.T12551= | Silent (SNP) | VAF 32/200 reads (16%) | catalogued as rs1317150911, COSV67451623; called by mutect2, varscan2
- MYH15 | c.1290A>G p.E430= | Silent (SNP) | VAF 21/200 reads (11%) | called by muse, mutect2
- MYH8 | c.4483C>T p.L1495= | Silent (SNP) | VAF 184/568 reads (32%) | catalogued as COSV67971143; called by muse, mutect2, varscan2
- MYO7A | c.3165C>T p.P1055= | Silent (SNP) | VAF 34/166 reads (20%) | catalogued as COSV101289090; called by muse, mutect2, varscan2
- NPAP1 | c.2685C>A p.S895= | Silent (SNP) | VAF 69/400 reads (17%) | called by muse, mutect2, varscan2
- NRSN1 | c.27G>A p.G9= | Silent (SNP) | VAF 27/159 reads (17%) | catalogued as rs771494990; called by muse, mutect2, varscan2
- NUGGC | c.1269C>A p.A423= | Silent (SNP) | VAF 60/246 reads (24%) | catalogued as rs762551437; called by muse, mutect2, varscan2
- OR2T5 | c.171C>T p.A57= | Silent (SNP) | VAF 80/560 reads (14%) | called by muse, varscan2
- OR51F1 | c.762G>T p.V254= | Silent (SNP) | VAF 23/106 reads (22%) | called by muse, varscan2
- OR5L1 | c.552C>A p.V184= | Silent (SNP) | VAF 28/207 reads (14%) | called by muse, mutect2, varscan2
- OR5R1 | c.423C>T p.C141= | Silent (SNP) | VAF 51/308 reads (17%) | called by muse, mutect2, varscan2
- OR9A4 | c.906G>T p.R302= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as COSV71885538; called by muse, mutect2, varscan2
- PARP9 | c.744G>A p.L248= | Silent (SNP) | VAF 13/280 reads (5%) | catalogued as COSV64451138; called by muse, mutect2
- PKHD1 | c.6213C>T p.N2071= | Silent (SNP) | VAF 104/651 reads (16%) | called by muse, mutect2, varscan2
- PKHD1 | c.2793C>A p.P931= | Silent (SNP) | VAF 100/624 reads (16%) | catalogued as COSV61891972; called by muse, mutect2, varscan2
- PKNOX1 | c.585G>T p.A195= | Silent (SNP) | VAF 25/156 reads (16%) | catalogued as rs199928026, COSV99372680; called by muse, mutect2, varscan2
- PLCH1 | c.3210C>A p.A1070= (on ENST00000340059 / NM_001130960.2; = p.A1062= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/290 reads (10%) | catalogued as rs1184499245; called by muse, mutect2
- PLD6 | c.222C>T p.P74= | Silent (SNP) | VAF 21/88 reads (24%) | called by muse, mutect2, varscan2
- PML | c.891G>C p.L297= | Silent (SNP) | VAF 27/175 reads (15%) | called by muse, mutect2, varscan2
- POLR3B | c.54G>T p.A18= | Silent (SNP) | VAF 130/784 reads (17%) | called by muse, mutect2, varscan2
- POMC | c.360C>T p.G120= | Silent (SNP) | VAF 9/81 reads (11%) | catalogued as rs774783651; called by mutect2, varscan2
- POU3F3 | c.1239C>T p.I413= | Silent (SNP) | VAF 52/335 reads (16%) | catalogued as rs777507294, COSV100796894; called by muse, mutect2, varscan2
- PPP4R3C | c.300T>A p.A100= | Silent (SNP) | VAF 41/195 reads (21%) | called by muse, mutect2, varscan2
- PREX1 | c.1758C>T p.F586= | Silent (SNP) | VAF 24/290 reads (8%) | called by muse, mutect2
- QTRT1 | c.360G>T p.V120= | Silent (SNP) | VAF 38/210 reads (18%) | called by muse, mutect2, varscan2
- RCAN2 | c.183G>T p.A61= | Silent (SNP) | VAF 90/399 reads (23%) | called by muse, mutect2, varscan2
- RING1 | c.759C>T p.P253= | Silent (SNP) | VAF 18/133 reads (14%) | catalogued as COSV63002304; called by muse, mutect2, varscan2
- SCN2A | c.4719G>T p.L1573= | Silent (SNP) | VAF 45/342 reads (13%) | called by muse, mutect2, varscan2
- SEC11C | c.159G>T p.V53= | Silent (SNP) | VAF 25/207 reads (12%) | called by muse, mutect2, varscan2
- SEC16A | c.1002G>A p.V334= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as rs1337947099; called by muse, mutect2
- SERPINA9 | c.1035C>A p.S345= | Silent (SNP) | VAF 18/151 reads (12%) | catalogued as COSV100098411; called by muse, mutect2, varscan2
- SHKBP1 | c.690C>T p.S230= | Silent (SNP) | VAF 15/64 reads (23%) | called by muse, mutect2, varscan2
- SIAE | c.1518C>T p.F506= | Silent (SNP) | VAF 45/532 reads (8%) | catalogued as rs1385512975; called by muse, mutect2
- SLC30A6 | c.198G>T p.L66= | Silent (SNP) | VAF 33/237 reads (14%) | called by muse, mutect2, varscan2
- SP4 | c.315T>C p.V105= | Silent (SNP) | VAF 13/221 reads (6%) | called by muse, mutect2
- SSC5D | c.540C>T p.A180= | Silent (SNP) | VAF 8/62 reads (13%) | called by mutect2, varscan2
- STXBP5 | c.1476A>T p.P492= | Silent (SNP) | VAF 57/366 reads (16%) | called by muse, mutect2, varscan2
- TDRD12 | c.363A>G p.R121= | Silent (SNP) | VAF 23/328 reads (7%) | called by muse, mutect2
- TNIP3 | c.573G>A p.E191= | Silent (SNP) | VAF 34/220 reads (15%) | called by muse, mutect2, varscan2
- TPBGL | c.213G>T p.T71= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as rs1363555716; called by muse, mutect2, varscan2
- TSEN34 | c.54G>T p.A18= | Silent (SNP) | VAF 33/182 reads (18%) | called by muse, mutect2, varscan2
- TSPAN15 | c.300G>T p.G100= | Silent (SNP) | VAF 54/276 reads (20%) | called by muse, mutect2, varscan2
- UNC13A | c.2397G>C p.R799= | Silent (SNP) | VAF 24/183 reads (13%) | called by muse, mutect2, varscan2
- ZBTB7B | c.1533G>C p.P511= (on ENST00000292176; = p.P545= on NM_001252406.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/100 reads (20%) | called by muse, mutect2
- ZNF609 | c.2997G>C p.T999= | Silent (SNP) | VAF 44/303 reads (15%) | called by muse, mutect2, varscan2
- ZNF638 | c.4743G>A p.K1581= | Silent (SNP) | VAF 26/305 reads (9%) | catalogued as COSV100040058; called by muse, mutect2
- ZNF691 | c.306C>T p.P102= (on ENST00000372502; = p.P71= on NM_015911.3) | Silent (SNP) | VAF 63/276 reads (23%) | catalogued as rs746944835; called by muse, varscan2
- ZNF729 | c.2838T>C p.N946= | Silent (SNP) | VAF 34/232 reads (15%) | called by muse, mutect2, varscan2
- ZNFX1 | c.1956C>A p.I652= | Silent (SNP) | VAF 52/297 reads (18%) | catalogued as COSV65577759; called by muse, mutect2, varscan2
- ABR | c.1962-136C>T | Intron (SNP) | VAF 16/51 reads (31%) | catalogued as rs766629134; called by muse, mutect2, varscan2
- AC006372.4 | n.130T>C | RNA (SNP) | VAF 40/193 reads (21%) | called by muse, mutect2, varscan2
- AC124067.2 | n.373A>G | RNA (SNP) | VAF 67/1274 reads (5%) | called by muse, mutect2
- AGXT2 | chr5:35049213 G>T | 5'Flank (SNP) | VAF 216/469 reads (46%) | called by muse, mutect2, varscan2
- ANKRD26P1 | n.1791C>A | RNA (SNP) | VAF 16/230 reads (7%) | called by muse, mutect2
- ARHGEF40 | c.*1190dup | 3'UTR (INS) | VAF 23/198 reads (12%) | called by mutect2, pindel, varscan2
- ATP2C2 | c.2333+120_2333+129del | Intron (DEL) | VAF 20/141 reads (14%) | called by mutect2, pindel, varscan2
- BIRC8 | n.1715del | RNA (DEL) | VAF 6/55 reads (11%) | called by mutect2, pindel
- C2orf83 | n.370G>T | RNA (SNP) | VAF 78/462 reads (17%) | called by muse, mutect2, varscan2
- CCDC188 | c.733-19T>C | Intron (SNP) | VAF 4/22 reads (18%) | catalogued as rs73150876; called by mutect2, varscan2
- CCNB1IP1 | c.297+413G>C | Intron (SNP) | VAF 15/125 reads (12%) | called by muse, mutect2, varscan2
- CEP44 | c.1124+15G>T | Intron (SNP) | VAF 24/122 reads (20%) | called by muse, mutect2, varscan2
- CNIH2 | c.*32C>A | 3'UTR (SNP) | VAF 35/154 reads (23%) | called by muse, mutect2, varscan2
- COL25A1 | c.1845+34_1845+45del | Intron (DEL) | VAF 58/383 reads (15%) | called by mutect2, pindel, varscan2
- COX15 | c.-7C>A | 5'UTR (SNP) | VAF 144/537 reads (27%) | catalogued as COSV99187388; called by muse, mutect2, varscan2
- CSHL1 | c.190+32T>A | Intron (SNP) | VAF 35/260 reads (13%) | called by muse, mutect2, varscan2
- CTBP1 | c.547+1922G>C | Intron (SNP) | VAF 73/298 reads (24%) | called by muse, mutect2, varscan2
- CYP2A7P1 | n.344C>T | RNA (SNP) | VAF 44/305 reads (14%) | called by muse, mutect2
- CYP2A7P1 | n.291G>C | RNA (SNP) | VAF 38/265 reads (14%) | called by muse, mutect2, varscan2
- ERAL1 | c.489+23C>T | Intron (SNP) | VAF 22/312 reads (7%) | called by muse, mutect2
- FN1 | c.5975-36C>A | Intron (SNP) | VAF 31/304 reads (10%) | called by muse, mutect2, varscan2
- FUS | c.190+26C>G | Intron (SNP) | VAF 29/207 reads (14%) | called by muse, mutect2, varscan2
- GALP | c.*22T>A | 3'UTR (SNP) | VAF 18/109 reads (17%) | called by muse, mutect2, varscan2
- GCM2 | c.-50T>C | 5'UTR (SNP) | VAF 67/376 reads (18%) | called by muse, mutect2, varscan2
- GPD1 | c.360+23G>A | Intron (SNP) | VAF 67/407 reads (16%) | called by muse, mutect2, varscan2
- HMBS | c.344+22G>T | Intron (SNP) | VAF 60/532 reads (11%) | called by muse, mutect2, varscan2
- HTR3D | chr3:184031795 C>A | 5'Flank (SNP) | VAF 79/271 reads (29%) | called by muse, mutect2, varscan2
- IGLL5 | chr22:22899574 G>AT | 3'Flank (INS) | VAF 17/120 reads (14%) | called by mutect2*, pindel, varscan2*
- ILVBL | c.*10G>T | 3'UTR (SNP) | VAF 81/571 reads (14%) | called by muse, mutect2, varscan2
- IQGAP2 | c.1612+1235T>C | Intron (SNP) | VAF 48/273 reads (18%) | called by muse, mutect2, varscan2
- KCNAB2 | c.804+491G>T | Intron (SNP) | VAF 58/284 reads (20%) | called by muse, mutect2, varscan2
- KDM5D | c.1372-2030G>C | Intron (SNP) | VAF 10/33 reads (30%) | called by muse, mutect2, varscan2
- LINC00602 | n.641G>T | RNA (SNP) | VAF 85/500 reads (17%) | catalogued as rs1458621460; called by muse, mutect2, varscan2
- LMBR1 | c.994-9C>T | Intron (SNP) | VAF 41/225 reads (18%) | called by muse, mutect2, varscan2
- LMCD1 | c.-4G>C | 5'UTR (SNP) | VAF 77/300 reads (26%) | called by muse, mutect2, varscan2
- LPAL2 | n.317C>T | RNA (SNP) | VAF 43/329 reads (13%) | called by muse, mutect2, varscan2
- MIR663B | n.73C>G | RNA (SNP) | VAF 25/151 reads (17%) | catalogued as rs1018168736; called by muse, mutect2, varscan2
- OR1F2P | n.747C>G | RNA (SNP) | VAF 39/275 reads (14%) | called by muse, mutect2, varscan2
- OR2L1P | n.736A>T | RNA (SNP) | VAF 26/360 reads (7%) | called by muse, mutect2
- OR2T35 | c.-13C>T | 5'UTR (SNP) | VAF 42/364 reads (12%) | called by muse, varscan2
- OR9Q1 | c.-15+53653G>T | Intron (SNP) | VAF 32/162 reads (20%) | called by muse, mutect2, varscan2
- PCBP2 | c.376-622G>T | Intron (SNP) | VAF 11/83 reads (13%) | called by muse, mutect2, varscan2
- PRPH | c.*36C>T | 3'UTR (SNP) | VAF 16/218 reads (7%) | called by muse, mutect2
- RABGGTB | c.111+300G>A | Intron (SNP) | VAF 19/107 reads (18%) | catalogued as rs776157035; called by muse, mutect2, varscan2
- RGR | chr10:84245074 A>T | 5'Flank (SNP) | VAF 32/173 reads (18%) | called by muse, mutect2, varscan2
- RPL15P13 | chr10:114899530 C>A | 5'Flank (SNP) | VAF 74/226 reads (33%) | called by muse, mutect2, varscan2
- SEMA5B | c.3091+59C>A | Intron (SNP) | VAF 52/201 reads (26%) | called by muse, mutect2, varscan2
- SFTPA1 | c.*959A>T | 3'UTR (SNP) | VAF 27/169 reads (16%) | called by muse, mutect2, varscan2
- SGIP1 | c.1571-937G>A | Intron (SNP) | VAF 25/119 reads (21%) | catalogued as rs764960430; called by muse, mutect2, varscan2
- SLC17A8 | c.*2G>A | 3'UTR (SNP) | VAF 24/179 reads (13%) | called by muse, mutect2, varscan2
- SLIT3 | c.1459+4607C>A | Intron (SNP) | VAF 29/151 reads (19%) | called by muse, mutect2, varscan2
- SMARCA4 | c.2617-97G>C | Intron (SNP) | VAF 13/122 reads (11%) | called by muse, mutect2, varscan2
- SPATA31C1 | n.2390C>A | RNA (SNP) | VAF 57/574 reads (10%) | catalogued as rs1245889557; called by muse, mutect2, varscan2
- SPATA8 | n.789G>A | RNA (SNP) | VAF 20/198 reads (10%) | called by muse, mutect2
- TRAPPC9 | chr8:140458369 G>C | 5'Flank (SNP) | VAF 54/165 reads (33%) | called by muse, mutect2, varscan2
- TRIP6 | c.999+361G>T | Intron (SNP) | VAF 18/141 reads (13%) | called by muse, mutect2, varscan2
- TRPM3 | c.1278+11C>T | Intron (SNP) | VAF 108/502 reads (22%) | called by muse, mutect2, varscan2
- TTN | c.10360+3677T>C | Intron (SNP) | VAF 53/268 reads (20%) | called by muse, mutect2, varscan2
- UBBP4 | n.543A>G | RNA (SNP) | VAF 54/660 reads (8%) | catalogued as rs762983276; called by muse, mutect2
- UBE2I | c.413+135G>T | Intron (SNP) | VAF 20/98 reads (20%) | catalogued as rs762476886; called by muse, mutect2
- WNK1 | c.2140-2721T>A | Intron (SNP) | VAF 51/192 reads (27%) | called by muse, mutect2, varscan2
- ZDHHC11 | c.1023+1091C>T | Intron (SNP) | VAF 26/285 reads (9%) | called by muse, mutect2
- ZNF727 | c.-99T>A | 5'UTR (SNP) | VAF 54/313 reads (17%) | called by muse, mutect2, varscan2
